Somatic mutation profile of tumor specimen MMRF_1439_1_BM_CD138pos (aliquot MMRF_1439_1_BM_CD138pos_T1_KAS5U_L01599) from MMRF case MMRF_1439, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 49.9 years (18,235 days).
Specimen MMRF_1439_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd6cd67d-a4f5-4a68-a4af-bbf9805bb1e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1439_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1439_1_PB_Whole_C2_KAS5U_L01608; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cd0b66d-0f86-4460-968c-0f6fd2ff7257

The open-access MAF lists 75 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 22, Silent 10, 5'Flank 4, Intron 3, 5'UTR 2, Nonsense Mutation 2, Frame Shift Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCK | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs764232985, CM020439, CM096810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by mutect2, varscan2
- AP2A1 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 83/161 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs372011505; called by muse, mutect2, varscan2
- DENND10 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as rs960009811; called by muse, mutect2, varscan2
- FAM20A | c.756C>A p.F252L | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV56836817; called by muse, mutect2, varscan2
- FBXO21 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as rs897057214, COSV57972188; called by muse, mutect2
- GALNT17 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 135/256 reads (53%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs184060184, COSV61157033, COSV61183777; called by muse, mutect2, varscan2
- IGLL5 | c.63G>C p.R21S | Missense Mutation (SNP) | VAF 39/39 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.362); catalogued as rs6003367, COSV101597229; called by muse, mutect2, varscan2
- MFSD13A | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 119/260 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as rs376006315; called by muse, mutect2, varscan2
- OR10A2 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 259/548 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs905406327; called by muse, mutect2, varscan2
- OR5D13 | c.537T>G p.F179L | Missense Mutation (SNP) | VAF 112/221 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62334494; called by muse, mutect2, varscan2
- OR8B8 | c.543C>G p.I181M | Missense Mutation (SNP) | VAF 103/218 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100045101; called by muse, mutect2, varscan2
- PLEKHG2 | c.3527C>T p.A1176V | Missense Mutation (SNP) | VAF 144/314 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs747488339; called by muse, mutect2, varscan2
- ST8SIA1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 56/58 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs1468430662, COSV53952769; called by muse, mutect2, varscan2
- TAS2R60 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 135/249 reads (54%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as COSV60330094; called by muse, mutect2, varscan2
- UBAC2 | c.685A>G p.S229G (on ENST00000403766 / NM_001144072.2; = p.S194G on NM_177967.4) | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs200720452; ClinVar: likely benign; called by muse, mutect2, varscan2
- VPS13D | c.2200G>A p.V734M | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs766208476; called by muse, mutect2, varscan2
- ZAN | c.2717C>T p.P906L | Missense Mutation (SNP) | VAF 207/425 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV61807781; called by muse, mutect2, varscan2
- ADGRV1 | c.16359A>C p.K5453N | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANK2 | c.4212del p.F1404Lfs*28 | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | called by mutect2, pindel, varscan2
- BRD7 | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CNOT8 | c.36C>G p.I12M | Missense Mutation (SNP) | VAF 115/239 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBN2 | c.1888G>T p.G630* | Nonsense Mutation (SNP) | VAF 94/182 reads (52%) | called by muse, mutect2, varscan2
- GABRA5 | c.87C>A p.G29= | Splice Region (SNP) | VAF 228/464 reads (49%) | called by muse, varscan2
- MED13 | c.2618G>C p.S873T | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- MFHAS1 | c.3095C>G p.P1032R | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR8J3 | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 117/251 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PJA2 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 123/278 reads (44%) | SIFT tolerated (0.99); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PRRC2B | c.2801G>T p.G934V | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- RUBCNL | c.996T>G p.Y332* | Nonsense Mutation (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- SPHKAP | c.2735C>A p.A912D | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBC1D17 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOX | c.1495A>G p.N499D | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BAZ2A | c.5262A>G p.S1754= | Silent (SNP) | VAF 54/93 reads (58%) | called by muse, mutect2, varscan2
- FRMPD2 | c.177C>T p.P59= | Silent (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- GRM1 | c.717C>T p.S239= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as rs956460815, COSV51266471; called by muse, mutect2, varscan2
- HDAC4 | c.1335T>G p.G445= | Silent (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- IGLV4-69 | c.171G>A p.Q57= | Silent (SNP) | VAF 91/177 reads (51%) | catalogued as rs779515651; called by muse, mutect2, varscan2
- NWD1 | c.813G>A p.V271= | Silent (SNP) | VAF 111/168 reads (66%) | catalogued as rs530057607; called by muse, mutect2, varscan2
- OSBPL6 | c.189C>A p.L63= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- RNF123 | c.732C>T p.S244= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as rs780652889; called by muse, mutect2, varscan2
- UNC80 | c.4821A>G p.A1607= | Silent (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- UNC80 | c.6936C>T p.T2312= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs1048714718, COSV55906726; called by muse, mutect2, varscan2
- ABTB2 | c.*187A>G | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.-340G>A | 5'UTR (SNP) | VAF 117/262 reads (45%) | catalogued as COSV104396715; called by muse, mutect2, varscan2
- ARL14EP | c.-63-1486A>G | Intron (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- ARMC8 | c.*2348C>G | 3'UTR (SNP) | VAF 60/117 reads (51%) | called by muse, mutect2, varscan2
- ARMC8 | c.*2349T>C | 3'UTR (SNP) | VAF 57/113 reads (50%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021452 C>G | 5'Flank (SNP) | VAF 50/108 reads (46%) | catalogued as rs1033927457; called by muse, mutect2
- BCL7A | chr12:122021454 T>A | 5'Flank (SNP) | VAF 48/108 reads (44%) | called by muse, mutect2
- C2orf88 | c.*2855A>C | 3'UTR (SNP) | VAF 86/169 reads (51%) | called by muse, mutect2, varscan2
- CCND1 | c.*1863G>A | 3'UTR (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- EIF4E | c.*9144A>G | 3'UTR (SNP) | VAF 75/151 reads (50%) | catalogued as rs998601723; called by muse, mutect2, varscan2
- ETV1 | c.*985T>G | 3'UTR (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- FDXR | chr17:74873009 C>T | 5'Flank (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2
- FZD1 | c.*459G>A | 3'UTR (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- GABRA5 | c.87-65A>C | Intron (SNP) | VAF 123/273 reads (45%) | called by muse, varscan2
- INO80D | c.*9632del | 3'UTR (DEL) | VAF 60/193 reads (31%) | called by mutect2, pindel, varscan2
- IQCE | c.*1685T>C | 3'UTR (SNP) | VAF 45/99 reads (45%) | catalogued as rs561611529, COSV58077714; called by muse, varscan2
- KIAA1217 | c.*1383C>T | 3'UTR (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- KLHL1 | c.*578A>G | 3'UTR (SNP) | VAF 41/72 reads (57%) | called by muse, mutect2, varscan2
- NLGN1 | c.*4563A>T | 3'UTR (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- OSBPL9 | chr1:51616919 T>G | 5'Flank (SNP) | VAF 41/80 reads (51%) | called by muse, mutect2, varscan2
- PARD3B | c.*690A>T | 3'UTR (SNP) | VAF 45/112 reads (40%) | called by muse, mutect2, varscan2
- PDPK1 | c.*454G>C | 3'UTR (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- PRDX2 | c.258-46T>C | Intron (SNP) | VAF 38/118 reads (32%) | called by muse, mutect2, varscan2
- PRR14L | c.*3832G>A | 3'UTR (SNP) | VAF 44/92 reads (48%) | catalogued as rs1025875020; called by muse, mutect2, varscan2
- RIMBP2 | c.*633A>C | 3'UTR (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*43G>A | 3'UTR (SNP) | VAF 13/31 reads (42%) | catalogued as rs201560003, COSV56137837; called by muse, mutect2, varscan2
- TAMALIN | c.*247C>T | 3'UTR (SNP) | VAF 58/122 reads (48%) | catalogued as rs947833247; called by muse, mutect2, varscan2
- TMPRSS11F | c.*96T>C | 3'UTR (SNP) | VAF 68/131 reads (52%) | called by muse, mutect2, varscan2
- TNRC18P2 | n.1249C>G | RNA (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.-137G>A | 5'UTR (SNP) | VAF 33/71 reads (46%) | catalogued as rs940486323, COSV59071529; called by muse, mutect2, varscan2
- VASH1 | c.*163del | 3'UTR (DEL) | VAF 63/90 reads (70%) | called by mutect2, pindel, varscan2
- ZNF142 | c.*3900A>T | 3'UTR (SNP) | VAF 26/45 reads (58%) | called by muse, mutect2, varscan2
